Somatic mutation profile of tumor specimen TARGET-30-PASCDX-01A (aliquot TARGET-30-PASCDX-01A-01D) from TARGET case TARGET-30-PASCDX, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.8 years (652 days).
Specimen TARGET-30-PASCDX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13bc8fa8-4b23-4b50-bc12-6dc720222f8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASCDX-10A (Blood Derived Normal), aliquot TARGET-30-PASCDX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a301c7fa-6138-4801-9866-4518a3d17b85

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2581G>T p.D861Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV53977460; called by muse, mutect2, varscan2
- ADAM28 | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56102242, COSV56105258; called by muse, mutect2, varscan2
- BRWD3 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64750565; called by muse, varscan2
- BRWD3 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956641, COSV64750571; called by muse, varscan2
- GYG2 | c.417+1G>A p.X139_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as COSV58550743; called by muse, mutect2, varscan2
- HNRNPU | c.836G>C p.R279P (on ENST00000283179; = p.R341P on NM_004501.3) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV51692442; called by muse, varscan2
- POFUT2 | c.757T>C p.F253L | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57959913; called by muse, mutect2, varscan2
- PYGO1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.011); catalogued as rs755117683, COSV57348611; called by muse, mutect2, varscan2
- SAMD4A | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.112); catalogued as COSV51884060; called by muse, mutect2, varscan2
- SDR16C5 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58127193; called by muse, mutect2, varscan2
- SPATA31E1 | c.3128C>A p.P1043Q | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57793253; called by muse, mutect2, varscan2
- ZNF180 | c.1447C>A p.H483N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55422317; called by muse, mutect2, varscan2
- ZSCAN22 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV61639346; called by muse, mutect2, varscan2
- IRS1 | c.699C>T p.P233= | Silent (SNP) | VAF 62/138 reads (45%) | catalogued as COSV59337794; called by muse, mutect2, varscan2
- KRT6B | c.1386C>A p.I462= | Silent (SNP) | VAF 75/185 reads (41%) | catalogued as COSV52882148, COSV52884775; called by muse, mutect2, varscan2
- PLAAT2 | c.192G>T p.L64= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as COSV55375153; called by muse, mutect2, varscan2
- RHBDF2 | c.1644C>A p.V548= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV51685400; called by muse, mutect2, varscan2
- DEPDC5 | c.*976G>A | 3'UTR (SNP) | VAF 118/284 reads (42%) | catalogued as rs748114243, COSV56702834; called by muse, mutect2, varscan2
